Somatic mutation profile of tumor specimen TARGET-10-PARSHV-09A (aliquot TARGET-10-PARSHV-09A-01D) from TARGET case TARGET-10-PARSHV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.9 years (5,080 days).
Specimen TARGET-10-PARSHV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df87fc12-f9bd-4dd2-a2ba-e91d0c4dcc06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARSHV-10A (Blood Derived Normal), aliquot TARGET-10-PARSHV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9799b2f3-25f9-4112-9d97-d207d5e3e047

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Frame Shift Del 2, 5'UTR 1, Frame Shift Ins 1, RNA 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 30/85 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ACTRT1 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as rs1030175845, COSV100947757; called by muse, mutect2, varscan2
- CRTAC1 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as rs762285795, COSV54011157; called by muse, mutect2, varscan2
- KLHL30 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745649884, COSV59975212; called by muse, mutect2, varscan2
- LOXL1 | c.1541C>T p.A514V | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745893746; called by muse, mutect2, varscan2
- PAX5 | c.239C>G p.P80R | Missense Mutation (SNP) | VAF 23/23 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63905332; called by muse, mutect2, varscan2
- COL6A5 | c.6624C>A p.F2208L (on ENST00000312481; = p.F2204L on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- IKZF1 | c.141_142insGGTTCTTCTA p.K48Gfs*6 | Frame Shift Ins (INS) | VAF 27/66 reads (41%) | called by mutect2, pindel, varscan2
- MYT1 | c.2042del p.N681Mfs*15 | Frame Shift Del (DEL) | VAF 29/102 reads (28%) | called by pindel*, varscan2
- PARP14 | c.4054_4060del p.E1352Lfs*10 | Frame Shift Del (DEL) | VAF 25/81 reads (31%) | called by mutect2, pindel, varscan2
- TEX14 | c.3261C>T p.D1087= (on ENST00000240361 / NM_001201457.2; = p.D1081= on NM_198393.4) | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs780956118; called by muse, mutect2, varscan2
- C5orf46 | c.-12C>T | 5'UTR (SNP) | VAF 27/81 reads (33%) | catalogued as rs1284307334, COSV59153816; called by muse, mutect2
- SLC22A20P | n.1328G>A | RNA (SNP) | VAF 30/62 reads (48%) | catalogued as rs540268861; called by muse, mutect2, varscan2
